Somatic mutation profile of tumor specimen 0DQ2NI from CCDI case PBCENX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 0.8 years (285 days).
Specimen 0DQ2NI: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d1c6e83-42cb-469e-876d-22117eb120fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2P3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6b21e46-3a88-4cb9-9230-7362b279883f

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK3 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1401678016; called by muse, mutect2, varscan2
- ARSJ | c.1589C>A p.A530E | Missense Mutation (SNP) | VAF 162/420 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLI4 | c.465C>A p.P155= | Silent (SNP) | VAF 17/333 reads (5%) | called by muse, mutect2
- PCDHA2 | c.1509G>A p.A503= | Silent (SNP) | VAF 142/329 reads (43%) | catalogued as COSV100974195, COSV65368060; called by muse, mutect2, varscan2
- SIX3 | c.792G>A p.A264= | Silent (SNP) | VAF 167/374 reads (45%) | catalogued as COSV53226911; called by muse, mutect2, varscan2
